Gene-level copy-number profile of tumor specimen TCGA-GC-A3RD-01A from TCGA case TCGA-GC-A3RD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 83.6 years (30,529 days).
Specimen TCGA-GC-A3RD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.ef20bcf0-7ef2-40a3-b01a-40866fe3fb73.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GC-A3RD-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8479bd14-5786-4947-b8c5-36b5b86aec0f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,206; copy number 2: 22,430; copy number 3: 19,634; copy number 4: 8,738; copy number 5: 4,564; copy number 6: 2,189; copy number 7: 457; copy number 8: 250; copy number 9: 221; copy number 10: 43; copy number 11: 7; copy number 12: 21; copy number 16: 3; copy number 34: 46; copy number 40: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GC-A3RD-01A-12D-A22Y-01): tumor purity 0.71, ploidy 2.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,811 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,155,579–47,180,339, 372 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:47,550,196–84,415,018, 590 genes, copy number 5–6 (broad region; genes not listed).
- chr3:90,261,414–198,222,513, 1,803 genes, copy number 5–6 (broad region; genes not listed).
- chr4:59,533,786–63,529,761, 28 genes, copy number 6: Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1, LINC02496, AC105420.1, MIR548AG1, LINC02271, ADGRL3, RPL17P19, AC020741.1, AC108161.1, Y_RNA, ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1, AC074087.2, AC074087.1, HMGN1P11, EXOC5P1, AC097491.1, LARP1BP1, AC093730.1.
- chr5:20,830,166–24,353,443, 31 genes, copy number 7: AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1.
- chr5:25,701,217–26,670,481, 10 genes, copy number 7: RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2, AC113347.1, AC113347.2, AC113347.3.
- chr5:27,111,569–28,287,807, 5 genes, copy number 6: RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103.
- chr5:28,624,657–28,624,763, 1 gene, copy number 6: RNU6-909P.
- chr5:34,373,028–45,895,970, 186 genes, copy number 5 (broad region; genes not listed).
- chr6:66,710,242–67,210,480, 3 genes, copy number 6: AL450336.1, RNU7-66P, AL591004.1.
- chr7:70,972–41,133,507, 729 genes, copy number 5–10 (broad region; genes not listed).
- chr7:77,043,721–77,198,626, 1 gene, copy number 5 (within-gene range 3–5): AC007000.3.
- chr7:77,083,787–79,453,667, 26 genes, copy number 5 (within-gene range 3–5): FAM185BP, AC007000.1, CCDC146, FGL2, AC098851.1, GSAP, AC004921.1, GCNT1P5, AC004921.2, PTPN12, APTR, RSBN1L, TMEM60, PHTF2, Y_RNA, AC004990.1, MAGI2, AC004808.2, AC004808.1, RPL13AP17, AC006043.1, AC007237.1, MAGI2-AS1, MAGI2-AS2, RNU6-337P, AC006355.1.
- chr8:37,421,341–40,520,158, 85 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr8:60,046,755–64,369,176, 56 genes, copy number 5 (within-gene range 3–5): AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2, LINC01414, AC069133.1, LINC01289.
- chr8:84,182,787–145,066,685, 967 genes, copy number 5–16 (within-gene range 3–16) (broad region; genes not listed).
- chr10:4,650,158–11,336,675, 119 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr10:16,436,943–18,681,639, 35 genes, copy number 5 (within-gene range 4–5): PTER, RNU2-18P, C1QL3, AL353576.1, RSU1, AC073367.1, AL365215.1, AL365215.2, CUBN, AC067747.1, TRDMT1, VIM-AS1, VIM, AL133415.1, ST8SIA6, ST8SIA6-AS1, Y_RNA, PRPF38AP2, HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1, TMEM236, MRC1, MIR511, AC069023.1, SLC39A12, SLC39A12-AS1, CACNB2, AL390783.1, AL450384.2, AL450384.1, NSUN6, ARL5B.
- chr10:45,016,080–45,147,221, 1 gene, copy number 6 (within-gene range 3–6): AL358394.3.
- chr10:45,099,487–45,315,608, 13 genes, copy number 6: RSU1P2, CUBNP3, AL358394.2, ANKRD54P1, ANKRD30BP3, MIR3156-1, AL358394.1, AL512324.3, AL512324.6, RNU6-1207P, CUBNP2, OR6D1P, OR13A1.
- chr11:66,664,998–89,808,575, 584 genes, copy number 5–7 (broad region; genes not listed).
- chr11:125,746,279–126,440,344, 32 genes, copy number 6: PATE1, PATE2, PATE3, PATE4, AP000842.3, HYLS1, PUS3, AP000842.2, DDX25, AP000842.1, VSIG10L2, CDON, NAP1L1P1, AP000821.1, AP000821.2, AP001893.3, AP001893.2, RPUSD4, AP001893.1, FAM118B, RNU4-86P, RN7SL351P, SRPRA, FOXRED1, RPL35AP26, TIRAP, AP001318.1, AP001318.2, DCPS, GSEC, ST3GAL4, AP001318.3.
- chr12:66,767–37,576,384, 851 genes, copy number 5 (broad region; genes not listed).
- chr12:68,805,011–71,032,083, 46 genes, copy number 34: AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1.
- chr12:101,696,947–101,873,623, 10 genes, copy number 40 (within-gene range 2–40): CHPT1, SYCP3, GNPTAB, RNU6-101P, AC063950.1, RNA5SP368, RNU6-172P, RNA5SP369, RNU6-1183P, HSPE1P4.
- chr19:33,386,950–48,391,551, 763 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr21:30,425,265–46,665,124, 464 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,206. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
